Somatic mutation profile of tumor specimen 0DU3LL from CCDI case PBCKLW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,186 days).
Specimen 0DU3LL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c68019d-8fe6-4d61-833a-2eb958e36b79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20710b1e-e0c1-439c-ba76-7b37eb9b18cf

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Ins 2, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 939/1634 reads (57%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 732/861 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOA1 | c.391_393del p.K131del | In Frame Del (DEL) | VAF 144/1030 reads (14%) | catalogued as rs532489785; called by pindel, varscan2
- ARHGAP23 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 60/1328 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.349); catalogued as rs571662439; called by muse, mutect2
- CHAF1A | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 55/555 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56674081; called by muse, mutect2, varscan2
- EXOC1 | c.113dup p.L38Ffs*8 | Frame Shift Ins (INS) | VAF 511/1433 reads (36%) | catalogued as rs770312166; called by mutect2, pindel, varscan2
- HHIPL2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 519/3790 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as rs548883263, COSV58564183; called by muse, mutect2, varscan2
- KIT | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 5112/14720 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55415662, COSV55419524; called by mutect2, varscan2
- RBPJL | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 371/1815 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1416517574, COSV59213388; called by muse, mutect2, varscan2
- VSIG2 | c.297dup p.T100Hfs*11 | Frame Shift Ins (INS) | VAF 109/708 reads (15%) | catalogued as rs766405238; called by mutect2, varscan2
- VWF | c.6034C>G p.L2012V | Missense Mutation (SNP) | VAF 688/1244 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV54612128; called by muse, mutect2, varscan2
- CERS3 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 225/897 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ECEL1 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 40/872 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2
- HERC4 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 40/1018 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- KIT | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 2810/10191 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTCH1 | c.991G>T p.V331F (on ENST00000373627 / NM_001271641.1; = p.V314F on NM_014341.2) | Missense Mutation (SNP) | VAF 620/1342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKDC | c.10573T>A p.Y3525N | Missense Mutation (SNP) | VAF 649/1545 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM63A | c.1940G>C p.R647P | Missense Mutation (SNP) | VAF 571/3303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC30A | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 1360/3029 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ZNF302 | c.574A>T p.N192Y (on ENST00000627982; = p.N113Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/1332 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2
- CSTF1 | c.1179G>A p.S393= | Silent (SNP) | VAF 431/997 reads (43%) | catalogued as rs531158050; called by muse, mutect2, varscan2
- HCLS1 | c.1071G>A p.E357= | Silent (SNP) | VAF 792/1752 reads (45%) | called by muse, mutect2, varscan2
- LPAR2 | c.627C>T p.T209= | Silent (SNP) | VAF 256/586 reads (44%) | called by muse, mutect2, varscan2
- PDGFRA | c.1143G>T p.L381= | Silent (SNP) | VAF 1186/2624 reads (45%) | catalogued as COSV99955800; called by muse, mutect2, varscan2
- PHRF1 | c.1062G>A p.P354= | Silent (SNP) | VAF 98/1050 reads (9%) | catalogued as rs747974960, COSV52761803; called by muse, mutect2
- TBC1D8 | c.903G>A p.A301= | Silent (SNP) | VAF 392/1785 reads (22%) | catalogued as rs368814168; called by muse, mutect2, varscan2
- TRAF7 | c.906C>T p.H302= | Silent (SNP) | VAF 521/1228 reads (42%) | catalogued as rs562213357, COSV100399398; called by muse, mutect2, varscan2
- DCD | chr12:54648391 T>A | 5'Flank (SNP) | VAF 12/112 reads (11%) | catalogued as rs1054009235, COSV53201351; called by muse, mutect2, varscan2
- FAM157A | n.574A>G | RNA (SNP) | VAF 34/64 reads (53%) | called by mutect2, varscan2
